Somatic mutation profile of tumor specimen 0DH732 from CCDI case PBBUCX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.4 years (5,242 days).
Specimen 0DH732: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2b3272f-2d17-4ba9-86b6-93e270b70c13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DH6ZR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be11b694-d20a-4a73-bc47-f80d5bd8b8e6

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 252/840 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.734G>C p.G245A | Missense Mutation (SNP) | VAF 321/866 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.374C>A p.T125K | Missense Mutation (SNP) | VAF 277/642 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs786201057, CM102351, CM157948, COSV52667346, COSV52673504, COSV52688693, COSV99037266; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF10 | c.1115G>A p.R372H (on ENST00000398564; = p.R347H on NM_014629.4) | Missense Mutation (SNP) | VAF 120/753 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.87); catalogued as rs149632587; called by muse, mutect2, varscan2
- DDX1 | c.2003G>C p.C668S | Missense Mutation (SNP) | VAF 282/744 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0.124); catalogued as rs1463789788; called by mutect2, varscan2
- SLC12A4 | c.2809C>T p.R937W | Missense Mutation (SNP) | VAF 30/1015 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as rs1317144601; called by muse, mutect2
- ZNF835 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 265/695 reads (38%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.938); catalogued as rs1262309917, COSV101606361; called by muse, mutect2, varscan2
- CAND2 | c.2011G>T p.A671S (on ENST00000456430 / NM_001162499.2; = p.A578S on NM_012298.3) | Missense Mutation (SNP) | VAF 304/1168 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CTNS | c.140+4A>T | Splice Region (SNP) | VAF 279/788 reads (35%) | called by muse, mutect2, varscan2
- SCRT2 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 262/678 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- WDR48 | c.1360G>T p.D454Y | Missense Mutation (SNP) | VAF 481/1752 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 48/1408 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- KIF22 | c.1260C>G p.A420= | Silent (SNP) | VAF 108/704 reads (15%) | called by muse, mutect2, varscan2
- KLHL23 | c.681C>T p.N227= | Silent (SNP) | VAF 34/1113 reads (3%) | called by muse, mutect2
- PRR23C | c.474C>T p.D158= | Silent (SNP) | VAF 446/1359 reads (33%) | catalogued as rs369973053, COSV68827136; called by muse, mutect2, varscan2
- RUFY4 | c.114G>A p.E38= | Silent (SNP) | VAF 265/704 reads (38%) | called by muse, mutect2, varscan2
- AC099782.1 | n.74+1960C>A | Intron (SNP) | VAF 136/1457 reads (9%) | catalogued as rs1297816287; called by muse, mutect2
